Somatic mutation profile of cancer-model specimen HCM-CSHL-0248-C19-85A (3D Organoid; aliquot HCM-CSHL-0248-C19-85A-01D-A78T-36), derived from the primary tumor of HCMI case HCM-CSHL-0248-C19, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Rectosigmoid junction; AJCC pathologic stage: Stage IIIB; Tumor grade: G2; Age at diagnosis: 53.4 years (19,501 days).
Specimen HCM-CSHL-0248-C19-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a42d4d35-74c6-4ade-ba9d-735e5c14becb.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0248-C19-10A (Blood Derived Normal), aliquot HCM-CSHL-0248-C19-10A-01D-A78T-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/69784fb7-0770-42b6-8942-d21585531671

The open-access MAF lists 161 somatic variants for this specimen: 121 protein-altering or splice-affecting, 30 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 101, Silent 30, Nonsense Mutation 11, Intron 5, Splice Region 4, 5'UTR 2, Frame Shift Del 2, RNA 2, Frame Shift Ins 1, 3'UTR 1, Splice Site 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.4132C>T p.Q1378* | Nonsense Mutation (SNP) | VAF 115/116 reads (99%) | hotspot (GDC flag); catalogued as rs121913329, CD1110399, CM095537, COSV57322261; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- KRAS | c.34G>A p.G12S | Missense Mutation (SNP) | VAF 51/136 reads (38%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.582); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: not provided / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.527G>A p.C176Y | Missense Mutation (SNP) | VAF 289/291 reads (99%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs786202962, COSV52660760, COSV52661329, COSV52678029; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ABCA8 | c.343G>T p.E115* | Nonsense Mutation (SNP) | VAF 8/17 reads (47%) | catalogued as COSV99285771; called by muse, mutect2, varscan2
- ACACB | c.565C>T p.R189W | Missense Mutation (SNP) | VAF 21/58 reads (36%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.945); catalogued as rs997993423; called by muse, mutect2, varscan2
- ADGRE4P | n.2430C>T | Splice Region (SNP) | VAF 28/67 reads (42%) | catalogued as rs939596340; called by muse, mutect2, varscan2
- AIFM1 | c.193G>T p.D65Y | Missense Mutation (SNP) | VAF 49/197 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.301); catalogued as rs763317252, COSV54857468; called by muse, mutect2, varscan2
- ANOS1 | c.482A>C p.K161T | Missense Mutation (SNP) | VAF 330/477 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52916948, COSV52917470; called by muse, mutect2, varscan2
- ASTL | c.1168G>A p.G390R | Missense Mutation (SNP) | VAF 121/431 reads (28%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.003); catalogued as rs757814790; called by muse, mutect2, varscan2
- CARD6 | c.170G>A p.S57N | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs147335843; called by muse, mutect2, varscan2
- CD248 | c.206G>A p.R69H | Missense Mutation (SNP) | VAF 125/125 reads (100%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.615); catalogued as rs751114440, COSV60936700; called by muse, mutect2, varscan2
- CFH | c.98T>C p.L33P | Missense Mutation (SNP) | VAF 15/53 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV62776439, COSV62777968; called by muse, varscan2
- COL6A3 | c.3271G>A p.V1091I | Missense Mutation (SNP) | VAF 49/152 reads (32%) | SIFT tolerated (0.21); PolyPhen benign (0.406); catalogued as rs373915980; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CRAT | c.1553G>A p.R518Q | Missense Mutation (SNP) | VAF 84/270 reads (31%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs767437298; called by muse, mutect2, varscan2
- CSMD1 | c.4900G>T p.E1634* (on ENST00000520002; = p.E1633* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 27/40 reads (68%) | catalogued as COSV59340823; called by muse, mutect2, varscan2
- CYB5R4 | c.1147A>T p.K383* | Nonsense Mutation (SNP) | VAF 8/16 reads (50%) | catalogued as rs371530268; called by muse, mutect2, varscan2
- DGKB | c.2054G>A p.R685Q | Missense Mutation (SNP) | VAF 13/42 reads (31%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.688); catalogued as rs61753126, COSV51769726; called by muse, mutect2, varscan2
- DMXL1 | c.7996G>T p.E2666* | Nonsense Mutation (SNP) | VAF 13/21 reads (62%) | catalogued as COSV60710872; called by muse, mutect2, varscan2
- ELFN1 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 41/116 reads (35%) | SIFT tolerated (0.14); PolyPhen benign (0.003); catalogued as rs780207326, COSV70033975; called by muse, mutect2, varscan2
- FAM9A | c.422A>G p.D141G | Missense Mutation (SNP) | VAF 22/35 reads (63%) | SIFT tolerated, low confidence (0.18); PolyPhen possibly damaging (0.736); catalogued as rs1309504625; called by muse, mutect2, varscan2
- FAXDC2 | c.72G>A p.M24I | Missense Mutation (SNP) | VAF 74/151 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0.003); catalogued as COSV100394092; called by muse, mutect2, varscan2
- FBXW7 | c.1787C>T p.S596F (on ENST00000281708 / NM_001349798.2; = p.S516F on NM_018315.5) | Missense Mutation (SNP) | VAF 26/48 reads (54%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55905007, COSV55968840, COSV55969630; called by muse, mutect2, varscan2
- FBXW7 | c.664C>T p.R222* (on ENST00000281708 / NM_001349798.2; = p.R142* on NM_018315.5) | Nonsense Mutation (SNP) | VAF 66/152 reads (43%) | catalogued as rs920052554, COSV55897378; called by muse, mutect2, varscan2
- FCAMR | c.323C>A p.S108* | Nonsense Mutation (SNP) | VAF 13/36 reads (36%) | catalogued as COSV61367607; called by muse, mutect2, varscan2
- FGF6 | c.367G>A p.V123M | Missense Mutation (SNP) | VAF 61/121 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs746672335, COSV57403329; called by muse, mutect2, varscan2
- GPR50 | c.1093G>A p.V365I | Missense Mutation (SNP) | VAF 87/298 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0.006); catalogued as rs374566932, COSV54443231; called by muse, mutect2, varscan2
- GPR84 | c.469C>A p.P157T | Missense Mutation (SNP) | VAF 40/133 reads (30%) | SIFT tolerated (0.22); PolyPhen benign (0.003); catalogued as rs765986834; called by muse, mutect2, varscan2
- HECW2 | c.40C>T p.R14C | Missense Mutation (SNP) | VAF 52/151 reads (34%) | SIFT tolerated, low confidence (0.24); PolyPhen probably damaging (0.993); catalogued as rs1332568073; called by muse, mutect2, varscan2
- KATNAL1 | c.344G>A p.R115H | Missense Mutation (SNP) | VAF 33/167 reads (20%) | SIFT deleterious (0.03); PolyPhen benign (0.014); catalogued as rs764643579, COSV66064741; called by muse, mutect2, varscan2
- LCE2B | c.239T>C p.L80P | Missense Mutation (SNP) | VAF 121/469 reads (26%) | SIFT tolerated, low confidence (0.22); PolyPhen benign (0.278); catalogued as COSV64227876; called by muse, mutect2, varscan2
- MAGEC1 | c.833C>A p.S278Y | Missense Mutation (SNP) | VAF 81/209 reads (39%) | SIFT tolerated, low confidence (0.05); PolyPhen benign (0.062); catalogued as rs1307594003; called by muse, mutect2, varscan2
- MAPK12 | c.943C>A p.H315N | Missense Mutation (SNP) | VAF 102/356 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as rs770945104; called by mutect2, varscan2
- MUC16 | c.8792A>G p.K2931R | Missense Mutation (SNP) | VAF 70/149 reads (47%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as rs960738464; called by muse, mutect2, varscan2
- NAV1 | c.3652C>T p.R1218* | Nonsense Mutation (SNP) | VAF 62/121 reads (51%) | catalogued as COSV55214307; called by muse, mutect2, varscan2
- NCAN | c.3581G>A p.R1194H | Missense Mutation (SNP) | VAF 62/147 reads (42%) | SIFT tolerated (0.06); PolyPhen benign (0.005); catalogued as rs368157092; called by muse, mutect2, varscan2
- NSUN5 | c.787C>T p.R263W | Missense Mutation (SNP) | VAF 107/108 reads (99%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs782131563; called by muse, mutect2, varscan2
- OR10G3 | c.358G>A p.A120T | Missense Mutation (SNP) | VAF 83/135 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.687); catalogued as COSV57809647; called by muse, mutect2, varscan2
- PCDH11X | c.208G>A p.G70R | Missense Mutation (SNP) | VAF 228/357 reads (64%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.918); catalogued as COSV53487981; called by muse, mutect2, varscan2
- PLIN4 | c.1922C>T p.T641M (on ENST00000301286; = p.T656M on NM_001367868.2) | Missense Mutation (SNP) | VAF 156/341 reads (46%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs200977488; called by muse, varscan2
- POLL | c.266T>C p.M89T | Missense Mutation (SNP) | VAF 223/452 reads (49%) | SIFT deleterious (0); PolyPhen benign (0.172); catalogued as COSV54577401; called by muse, mutect2, varscan2
- PPP1R9B | c.2155C>T p.R719C | Missense Mutation (SNP) | VAF 140/279 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1374299692; called by muse, mutect2, varscan2
- PSMA4 | c.50G>A p.R17H | Missense Mutation (SNP) | VAF 12/30 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as rs750216737, COSV50385028; called by muse, mutect2
- PTCHD1 | c.292G>A p.V98I | Missense Mutation (SNP) | VAF 91/322 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs771692412; called by muse, mutect2, varscan2
- RALYL | c.553G>A p.G185R | Missense Mutation (SNP) | VAF 30/67 reads (45%) | SIFT tolerated (0.31); PolyPhen possibly damaging (0.449); catalogued as rs1433236969, COSV101569435; called by muse, mutect2, varscan2
- RBP3 | c.2278G>T p.V760L | Missense Mutation (SNP) | VAF 256/513 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0.003); catalogued as rs782109249; called by muse, mutect2, varscan2
- RMND5B | c.285+8C>T | Splice Region (SNP) | VAF 77/190 reads (41%) | catalogued as rs770068571, COSV57743783; called by muse, mutect2, varscan2
- RYR2 | c.12541G>A p.G4181R | Missense Mutation (SNP) | VAF 90/234 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs775477470, COSV63669927; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SEL1L2 | c.1253A>G p.Y418C | Missense Mutation (SNP) | VAF 64/177 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53159096; called by muse, mutect2, varscan2
- SH2D2A | c.268G>A p.G90R | Missense Mutation (SNP) | VAF 47/186 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs759722611; called by muse, mutect2, varscan2
- SLC35E3 | c.294C>A p.N98K | Missense Mutation (SNP) | VAF 31/123 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1462980729; called by muse, mutect2, varscan2
- SLC4A1 | c.2479C>T p.R827W | Missense Mutation (SNP) | VAF 193/385 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.959); catalogued as rs780549162; called by muse, mutect2, varscan2
- SOHLH2 | c.1067C>T p.A356V | Missense Mutation (SNP) | VAF 22/145 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.009); catalogued as rs144696055, COSV65903471, COSV65904086; called by muse, mutect2, varscan2
- STARD9 | c.6781G>A p.V2261I | Missense Mutation (SNP) | VAF 69/69 reads (100%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs867845466; called by muse, mutect2, varscan2
- TTBK1 | c.3725C>T p.A1242V | Missense Mutation (SNP) | VAF 72/72 reads (100%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.017); catalogued as rs1383120100; called by muse, mutect2, varscan2
- TTN | c.1088C>T p.T363M | Missense Mutation (SNP) | VAF 80/260 reads (31%) | PolyPhen benign (0.01); catalogued as rs199590524, COSV99045813; called by muse, mutect2, varscan2
- WDR91 | c.1759C>T p.R587W | Missense Mutation (SNP) | VAF 161/161 reads (100%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs761361253; called by muse, mutect2, varscan2
- WNK4 | c.1522C>T p.R508C | Missense Mutation (SNP) | VAF 187/342 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.952); catalogued as rs201947637, COSV99889410; called by muse, mutect2, varscan2
- ZNF85 | c.374A>C p.K125T | Missense Mutation (SNP) | VAF 9/21 reads (43%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.878); catalogued as COSV56021564, COSV56022043; called by muse, mutect2
- ADGRG6 | c.770G>A p.W257* | Nonsense Mutation (SNP) | VAF 32/56 reads (57%) | called by muse, mutect2, varscan2
- ALS2CL | c.786+2_786+6del p.X262_splice | Splice Site (DEL) | VAF 36/86 reads (42%) | called by mutect2, pindel, varscan2
- ANAPC1 | c.809C>T p.T270I | Missense Mutation (SNP) | VAF 21/102 reads (21%) | SIFT tolerated (0.18); PolyPhen benign (0); called by muse, mutect2, varscan2
- BMX | c.1523T>C p.L508P | Missense Mutation (SNP) | VAF 63/241 reads (26%) | SIFT tolerated (0.07); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CACNA2D1 | c.2764-5T>C | Splice Region (SNP) | VAF 50/147 reads (34%) | called by muse, mutect2, varscan2
- CALCRL | c.1372A>T p.N458Y | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.109); called by muse, mutect2, varscan2
- CBY3 | c.120G>C p.Q40H | Missense Mutation (SNP) | VAF 59/113 reads (52%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.398); called by muse, mutect2, varscan2
- CD6 | c.1417C>T p.P473S | Missense Mutation (SNP) | VAF 144/144 reads (100%) | SIFT tolerated (0.13); PolyPhen benign (0.038); called by muse, varscan2
- CDH23 | c.5915C>T p.S1972F | Missense Mutation (SNP) | VAF 78/155 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.851); called by muse, mutect2, varscan2
- CEP43 | c.704T>C p.L235S | Missense Mutation (SNP) | VAF 58/91 reads (64%) | SIFT tolerated (0.11); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- CHM | c.836C>G p.A279G | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2
- COL7A1 | c.8820T>G p.G2940= | Splice Region (SNP) | VAF 173/325 reads (53%) | called by muse, mutect2, varscan2
- CRACD | c.2608A>G p.K870E | Missense Mutation (SNP) | VAF 98/204 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- DYNC2H1 | c.7355A>C p.K2452T | Missense Mutation (SNP) | VAF 12/26 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- EIF2S1 | c.465T>A p.H155Q | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT tolerated (0.33); PolyPhen benign (0); called by muse, mutect2, varscan2
- EPB42 | c.1877T>C p.L626P (on ENST00000441366 / NM_001114134.2; = p.L656P on NM_000119.3) | Missense Mutation (SNP) | VAF 17/378 reads (4%) | SIFT tolerated (0.2); PolyPhen benign (0.435); called by muse, mutect2
- FAM83B | c.1577C>G p.P526R | Missense Mutation (SNP) | VAF 30/59 reads (51%) | SIFT tolerated (0.36); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- FGD5 | c.2916C>G p.S972R | Missense Mutation (SNP) | VAF 61/96 reads (64%) | SIFT tolerated (0.08); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- FRAS1 | c.3397G>A p.G1133S | Missense Mutation (SNP) | VAF 52/106 reads (49%) | SIFT tolerated (0.28); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- HARBI1 | c.887G>T p.C296F | Missense Mutation (SNP) | VAF 71/134 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- HOXC9 | c.382G>A p.A128T | Missense Mutation (SNP) | VAF 119/345 reads (34%) | SIFT tolerated (0.9); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- HSPA6 | c.1676G>T p.S559I | Missense Mutation (SNP) | VAF 47/217 reads (22%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.361); called by muse, mutect2, varscan2
- HTATSF1 | c.1039T>C p.W347R | Missense Mutation (SNP) | VAF 49/167 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- HTR5A | c.478G>A p.V160I | Missense Mutation (SNP) | VAF 414/416 reads (100%) | SIFT tolerated (0.52); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- KDM6A | c.1847C>G p.T616S | Missense Mutation (SNP) | VAF 81/295 reads (27%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- KIAA1755 | c.1596C>A p.S532R | Missense Mutation (SNP) | VAF 37/116 reads (32%) | SIFT tolerated (0.2); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- KIFAP3 | c.1861C>A p.H621N | Missense Mutation (SNP) | VAF 16/88 reads (18%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- LNPEP | c.2251G>T p.D751Y | Missense Mutation (SNP) | VAF 20/30 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); called by muse, varscan2
- MAN1A1 | c.92C>T p.S31L | Missense Mutation (SNP) | VAF 16/58 reads (28%) | SIFT tolerated (0.13); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- MAP3K21 | c.751C>G p.L251V | Missense Mutation (SNP) | VAF 123/262 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- METTL14 | c.1298A>T p.N433I | Missense Mutation (SNP) | VAF 39/88 reads (44%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.088); called by muse, mutect2, varscan2
- MPDZ | c.1860A>C p.K620N | Missense Mutation (SNP) | VAF 36/105 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NBEA | c.8684A>C p.K2895T | Missense Mutation (SNP) | VAF 43/214 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- NID2 | c.4075C>T p.H1359Y | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2, varscan2
- NR3C2 | c.1823A>T p.D608V | Missense Mutation (SNP) | VAF 61/127 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NSRP1 | c.775G>A p.E259K | Missense Mutation (SNP) | VAF 22/46 reads (48%) | SIFT tolerated (0.51); PolyPhen benign (0); called by muse, varscan2
- NT5C3A | c.314T>G p.I105S (on ENST00000610140 / NM_001374335.1; = p.I71S on NM_016489.13) | Missense Mutation (SNP) | VAF 13/44 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PCDHGB5 | c.2138G>A p.R713H | Missense Mutation (SNP) | VAF 129/245 reads (53%) | SIFT tolerated (0.28); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PDE4D | c.139C>G p.Q47E | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2
- PGLYRP4 | c.185G>A p.G62E | Missense Mutation (SNP) | VAF 159/390 reads (41%) | SIFT deleterious (0.05); PolyPhen benign (0.172); called by muse, mutect2, varscan2
- PIP4K2B | c.247C>G p.L83V | Missense Mutation (SNP) | VAF 62/121 reads (51%) | SIFT deleterious (0.01); PolyPhen benign (0.442); called by muse, mutect2, varscan2
- PLGRKT | c.12A>G p.I4M | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.13); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PLK2 | c.1307A>C p.E436A | Missense Mutation (SNP) | VAF 36/95 reads (38%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- POTEM | c.197G>C p.R66P | Missense Mutation (SNP) | VAF 126/1172 reads (11%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.071); called by muse, varscan2
- PRDM2 | c.3568A>G p.I1190V | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- PRELP | c.57del p.G20Afs*122 | Frame Shift Del (DEL) | VAF 19/78 reads (24%) | called by mutect2, pindel, varscan2
- PROM2 | c.725G>A p.R242K | Missense Mutation (SNP) | VAF 164/219 reads (75%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- REV1 | c.2581G>T p.A861S | Missense Mutation (SNP) | VAF 27/87 reads (31%) | SIFT tolerated (0.39); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- RO60 | c.1224A>T p.K408N | Missense Mutation (SNP) | VAF 21/50 reads (42%) | SIFT tolerated (0.22); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- RYR2 | c.6763T>A p.L2255I | Missense Mutation (SNP) | VAF 14/85 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SHROOM2 | c.3166C>T p.L1056F | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0); called by muse, mutect2, varscan2
- TENT5D | c.569A>G p.K190R | Missense Mutation (SNP) | VAF 16/45 reads (36%) | SIFT tolerated (0.12); PolyPhen benign (0.089); called by muse, mutect2, varscan2
- TMEM200C | c.1139C>T p.A380V | Missense Mutation (SNP) | VAF 99/232 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- TSC2 | c.1080_1091del p.L361_I364del | In Frame Del (DEL) | VAF 220/261 reads (84%) | called by mutect2, pindel, varscan2
- TTN | c.73393A>C p.T24465P (on ENST00000591111; = p.T17041P on NM_003319.4) | Missense Mutation (SNP) | VAF 29/75 reads (39%) | PolyPhen possibly damaging (0.775); called by muse, mutect2, varscan2
- TTN | c.24661T>A p.S8221T (on ENST00000591111; = p.S7294T on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 42/58 reads (72%) | PolyPhen benign (0.039); called by muse, mutect2
- TXNRD3 | c.80G>T p.G27V | Missense Mutation (SNP) | VAF 28/49 reads (57%) | SIFT tolerated, low confidence (0.51); PolyPhen benign (0.344); called by muse, mutect2, varscan2
- XPOT | c.2826G>T p.Q942H | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.647); called by muse, mutect2, varscan2
- XPOT | c.2827C>T p.Q943* | Nonsense Mutation (SNP) | VAF 20/84 reads (24%) | called by muse, mutect2, varscan2
- ZFP36L2 | c.111dup p.T38Dfs*46 | Frame Shift Ins (INS) | VAF 71/348 reads (20%) | called by mutect2, pindel, varscan2
- ZNF267 | c.916C>T p.Q306* | Nonsense Mutation (SNP) | VAF 12/12 reads (100%) | called by muse, mutect2, varscan2
- ZNF521 | c.3571G>A p.E1191K | Missense Mutation (SNP) | VAF 20/33 reads (61%) | SIFT tolerated (0.08); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- ZNF84 | c.2158_2161del p.F720Hfs*15 | Frame Shift Del (DEL) | VAF 18/20 reads (90%) | called by mutect2, varscan2
- ABL2 | c.495G>A p.V165= (on ENST00000502732 / NM_007314.4; = p.V150= on NM_005158.5) | Silent (SNP) | VAF 84/385 reads (22%) | called by muse, mutect2, varscan2
- CCDC80 | c.2712G>A p.A904= | Silent (SNP) | VAF 197/322 reads (61%) | catalogued as COSV99245019; called by muse, mutect2, varscan2
- CDH2 | c.1839C>T p.C613= | Silent (SNP) | VAF 18/18 reads (100%) | catalogued as rs754880999, COSV52275510; called by muse, mutect2, varscan2
- CLEC4M | c.1029C>T p.D343= | Silent (SNP) | VAF 56/152 reads (37%) | catalogued as rs370711365; called by muse, mutect2, varscan2
- COL6A3 | c.3501C>T p.I1167= | Silent (SNP) | VAF 121/435 reads (28%) | catalogued as rs199998363, COSV55112672; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CYLC1 | c.210G>A p.Q70= | Silent (SNP) | VAF 14/23 reads (61%) | called by muse, varscan2
- DCAF12L1 | c.816C>A p.G272= | Silent (SNP) | VAF 112/161 reads (70%) | called by muse, mutect2, varscan2
- DTD2 | c.135C>T p.Y45= | Silent (SNP) | VAF 6/28 reads (21%) | catalogued as rs766892797, COSV60428385; called by muse, mutect2, varscan2
- ECEL1 | c.87C>T p.R29= | Silent (SNP) | VAF 73/187 reads (39%) | called by muse, mutect2, varscan2
- EDIL3 | c.1065A>G p.K355= | Silent (SNP) | VAF 81/156 reads (52%) | catalogued as rs147685138; called by muse, mutect2, varscan2
- FBN3 | c.2040T>C p.G680= | Silent (SNP) | VAF 33/84 reads (39%) | called by muse, mutect2, varscan2
- FOSL2 | c.798G>A p.V266= | Silent (SNP) | VAF 140/233 reads (60%) | called by muse, mutect2, varscan2
- MYH13 | c.2892C>G p.T964= | Silent (SNP) | VAF 84/84 reads (100%) | called by muse, mutect2, varscan2
- NCOR2 | c.2712C>T p.T904= | Silent (SNP) | VAF 41/91 reads (45%) | called by muse, mutect2, varscan2
- NLRP4 | c.1125C>T p.F375= | Silent (SNP) | VAF 77/247 reads (31%) | catalogued as rs373243158, COSV56710515; called by muse, mutect2, varscan2
- NRK | c.4413C>A p.G1471= | Silent (SNP) | VAF 20/44 reads (45%) | called by muse, mutect2, varscan2
- PDE12 | c.1404C>T p.L468= | Silent (SNP) | VAF 4/10 reads (40%) | catalogued as rs774465401; called by muse, mutect2, varscan2
- PUM3 | c.1764G>A p.K588= | Silent (SNP) | VAF 33/49 reads (67%) | catalogued as rs1363434044, COSV65896562; called by muse, mutect2, varscan2
- RBPJL | c.1191C>T p.G397= | Silent (SNP) | VAF 43/136 reads (32%) | catalogued as rs1336661307; called by muse, mutect2, varscan2
- REXO1 | c.1731C>T p.S577= | Silent (SNP) | VAF 95/165 reads (58%) | catalogued as COSV50074875; called by muse, mutect2, varscan2
- SPOCK2 | c.696C>T p.A232= | Silent (SNP) | VAF 60/196 reads (31%) | catalogued as rs370648887; called by muse, mutect2, varscan2
- TMEM132C | c.2460C>T p.H820= | Silent (SNP) | VAF 137/137 reads (100%) | catalogued as rs561705907, COSV59414400; called by muse, mutect2, varscan2
- TMPRSS15 | c.2844T>C p.Y948= | Silent (SNP) | VAF 29/85 reads (34%) | called by muse, mutect2, varscan2
- TNFRSF11A | c.1026G>A p.Q342= | Silent (SNP) | VAF 278/278 reads (100%) | called by muse, mutect2, varscan2
- TTC17 | c.945G>T p.V315= | Silent (SNP) | VAF 95/95 reads (100%) | catalogued as COSV50013380; called by muse, mutect2, varscan2
- UNC13A | c.390C>G p.P130= | Silent (SNP) | VAF 42/71 reads (59%) | catalogued as COSV53187515; called by muse, mutect2, varscan2
- ZFP82 | c.681A>G p.E227= | Silent (SNP) | VAF 49/140 reads (35%) | called by muse, mutect2, varscan2
- ZNF418 | c.832C>A p.R278= | Silent (SNP) | VAF 22/100 reads (22%) | catalogued as rs762996822, COSV68675429, COSV68675779; called by muse, varscan2
- ZNF783 | c.66G>A p.S22= | Silent (SNP) | VAF 94/94 reads (100%) | catalogued as rs766377882; called by muse, mutect2
- ZNF835 | c.372G>A p.A124= | Silent (SNP) | VAF 273/407 reads (67%) | catalogued as COSV101606327; called by muse, mutect2, varscan2
- AC009139.2 | n.64+1889T>C | Intron (SNP) | VAF 14/37 reads (38%) | called by muse, mutect2, varscan2
- ACOT12 | c.-5T>A | 5'UTR (SNP) | VAF 82/152 reads (54%) | called by muse, mutect2, varscan2
- AMPH | c.1182+1388T>G | Intron (SNP) | VAF 21/52 reads (40%) | catalogued as COSV100341901; called by muse, mutect2, varscan2
- CNTN4 | c.*7T>G | 3'UTR (SNP) | VAF 40/74 reads (54%) | catalogued as COSV100638829; called by muse, mutect2, varscan2
- COL11A1 | c.-12C>A | 5'UTR (SNP) | VAF 221/221 reads (100%) | catalogued as COSV100617542; called by muse, mutect2, varscan2
- DEFB124 | c.58+19T>C | Intron (SNP) | VAF 83/162 reads (51%) | called by muse, varscan2
- PZP | c.428-22T>C | Intron (SNP) | VAF 53/105 reads (50%) | called by muse, mutect2, varscan2
- SF3B1 | c.416-345G>C | Intron (SNP) | VAF 20/106 reads (19%) | called by muse, mutect2, varscan2
- SSPOP | n.15346G>A | RNA (SNP) | VAF 139/464 reads (30%) | called by muse, mutect2, varscan2
- XIST | n.10946T>G | RNA (SNP) | VAF 6/27 reads (22%) | called by muse, mutect2, varscan2
